Somatic mutation profile of tumor specimen TCGA-M7-A722-01A (aliquot TCGA-M7-A722-01A-12D-A364-08) from TCGA case TCGA-M7-A722, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.4 years (23,880 days).
Specimen TCGA-M7-A722-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 273040f7-c986-4ed7-b0bd-abab819364d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-M7-A722-10B (Blood Derived Normal), aliquot TCGA-M7-A722-10B-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77f88a5b-79af-4ecd-9365-d238a4173488

The open-access MAF lists 31 somatic variants for this specimen: 27 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 3, Intron 1, Splice Site 1, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- FOXA1 | c.745_756del p.D249_N252del | In Frame Del (DEL) | VAF 9/22 reads (41%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 33/90 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BSN | c.11038C>T p.R3680W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs1435701515, COSV56515595; called by muse, mutect2, varscan2
- CCDC80 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV99245451; called by muse, mutect2, varscan2
- CHD3 | c.1618dup p.R540Pfs*47 | Frame Shift Ins (INS) | VAF 28/72 reads (39%) | catalogued as rs747299117; called by mutect2, varscan2
- CLASP1 | c.2285G>A p.R762Q | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs778058950, COSV55312694; called by muse, mutect2, varscan2
- ENPP4 | c.1160G>T p.G387V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100320497; called by muse, mutect2
- FZD10 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV99969667; called by muse, mutect2, varscan2
- GPR6 | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.557); catalogued as COSV99254644; called by muse, mutect2, varscan2
- GRIA2 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV99646276; called by muse, mutect2, varscan2
- GTPBP1 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs759324893, COSV53283830; called by muse, mutect2, varscan2
- ITPR2 | c.4016G>T p.G1339V | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101190287; called by muse, mutect2, varscan2
- KLHL6 | c.1451A>C p.D484A | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100385132; called by muse, mutect2, varscan2
- LDHAL6A | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as rs368803699; called by muse, mutect2, varscan2
- LRRC4C | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776146097, COSV53424696; called by muse, mutect2, varscan2
- NCAN | c.3521C>T p.P1174L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765282686, COSV99388609; called by muse, mutect2, varscan2
- OR52L1 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as COSV100176409; called by muse, mutect2, varscan2
- RFT1 | c.150-1G>C p.X50_splice | Splice Site (SNP) | VAF 16/46 reads (35%) | catalogued as COSV99965652; called by muse, mutect2, varscan2
- SELENON | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1399091746, COSV100823610; called by muse, mutect2, varscan2
- SIPA1L2 | c.2932G>A p.G978S | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99479987; called by muse, mutect2
- SORCS3 | c.1901G>T p.W634L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as rs1474991676, COSV100865738; called by muse, mutect2, varscan2
- TKTL2 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV99761826; called by muse, mutect2, varscan2
- TTN | c.84844T>C p.S28282P (on ENST00000591111; = p.S20858P on NM_003319.4) | Missense Mutation (SNP) | VAF 34/72 reads (47%) | PolyPhen possibly damaging (0.563); catalogued as COSV100635615; called by muse, mutect2, varscan2
- VN1R2 | c.845G>T p.S282I | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV100448244; called by muse, mutect2, varscan2
- BBS2 | c.1679_1681delinsGC p.D560Gfs*23 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | called by pindel, varscan2*
- MUC5AC | c.989G>T p.G330V | Missense Mutation (SNP) | VAF 3/52 reads (6%) | SIFT deleterious (0.01); called by muse, mutect2
- LRRIQ4 | c.264G>A p.P88= | Silent (SNP) | VAF 43/105 reads (41%) | catalogued as rs759764903, COSV100540444; called by muse, mutect2, varscan2
- MORC1 | c.2415G>T p.S805= | Silent (SNP) | VAF 43/118 reads (36%) | catalogued as rs777002185, COSV51725413, COSV99228207; called by muse, mutect2, varscan2
- SNU13 | c.252C>T p.R84= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV99316868; called by muse, mutect2, varscan2
- PIK3CD | c.-138+2484G>A | Intron (SNP) | VAF 17/39 reads (44%) | catalogued as rs372172762; called by muse, mutect2, varscan2
